Somatic mutation profile of tumor specimen TCGA-61-1895-01A (aliquot TCGA-61-1895-01A-01W-0639-09) from TCGA case TCGA-61-1895, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 52.2 years (19,060 days).
Specimen TCGA-61-1895-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96ff6c09-5300-4bec-b306-eaa13ce9bfba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1895-11A (Solid Tissue Normal), aliquot TCGA-61-1895-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38fb2b68-3804-408a-9426-67cc9d68877d

The open-access MAF lists 73 somatic variants for this specimen: 61 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 10, Splice Site 5, Frame Shift Ins 3, Frame Shift Del 3, Nonsense Mutation 3, In Frame Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC004593.2 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV56098385; called by muse, mutect2, varscan2
- ADAM9 | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65952412; called by muse, mutect2, varscan2
- AGAP1 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV58335142; called by muse, mutect2
- AGFG2 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV53547893; called by muse, mutect2
- AQP11 | c.445A>G p.S149G | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57992958; called by muse, mutect2, varscan2
- ATP8B1 | c.1828C>G p.P610A | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV52178614; called by muse, mutect2, varscan2
- C10orf71 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60510735; called by muse, mutect2, varscan2
- CAAP1 | c.531dup p.L178Tfs*11 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | catalogued as rs1312369665; called by mutect2, pindel, varscan2
- CACNA2D4 | c.2281G>T p.G761C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765886, COSV99766184; called by muse, mutect2
- CHD3 | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57878426; called by muse, mutect2, varscan2
- CLEC4M | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.702); catalogued as COSV99940730; called by muse, mutect2
- COL6A3 | c.5525G>T p.G1842V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM1413880, COSV55101483; called by muse, mutect2, varscan2
- DCTN2 | c.337C>A p.L113M (on ENST00000548249 / NM_001261413.2; = p.L118M on NM_006400.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63075946; called by mutect2, varscan2
- DSG4 | c.3013C>A p.Q1005K | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1235291417, COSV57395171; called by muse, mutect2, varscan2
- DST | c.22289G>A p.R7430Q (on ENST00000361203 / NM_001374722.1; = p.R5140Q on NM_015548.5) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as rs375978950; called by muse, mutect2, varscan2
- ECH1 | c.285G>T p.K95N | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.776); catalogued as COSV55489707, COSV99669654, COSV99669699; called by muse, mutect2
- EPB41 | c.2160T>A p.N720K (on ENST00000343067 / NM_001166005.2; = p.N478K on NM_004437.4) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as COSV58051821; called by muse, mutect2, varscan2
- ERBIN | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99397525; called by muse, mutect2
- F12 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99499857; called by muse, mutect2
- GANAB | c.2542G>T p.D848Y | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642129; called by muse, mutect2
- GDPD4 | c.1472+2T>G p.X491_splice | Splice Site (SNP) | VAF 13/47 reads (28%) | catalogued as COSV60021528; called by muse, mutect2, varscan2
- HECTD1 | c.3163C>T p.R1055* | Nonsense Mutation (SNP) | VAF 50/155 reads (32%) | catalogued as COSV67948315; called by muse, mutect2, varscan2
- IGFN1 | c.1346A>G p.K449R (on ENST00000295591 / NM_001367841.1; = p.K2906R on NM_001164586.2) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV55180136; called by muse, mutect2, varscan2
- LCLAT1 | c.1233G>C p.K411N | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as COSV58376525; called by muse, mutect2, varscan2
- LMO7 | c.2522G>A p.R841H (on ENST00000357063; = p.R522H on NM_005358.5) | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs760259550, COSV58528993; called by muse, mutect2, varscan2
- LRIT2 | c.1150G>C p.A384P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV60565083; called by muse, mutect2, varscan2
- LRP6 | c.2953C>G p.R985G | Missense Mutation (SNP) | VAF 77/443 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV53791712; called by muse, mutect2, varscan2
- MXRA5 | c.6131C>T p.A2044V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV54225340; called by muse, mutect2, varscan2
- NDST4 | c.962A>T p.N321I | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV52130595; called by muse, mutect2, varscan2
- OAS3 | c.1020G>C p.W340C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57447966; called by muse, mutect2, varscan2
- OR10H3 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV100008462; called by muse, mutect2
- OR1J1 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99403236; called by muse, mutect2
- OR2AG1 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0.02); catalogued as rs1334505442, COSV56626503; called by muse, mutect2, varscan2
- PCDHB3 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV50606046; called by muse, mutect2, varscan2
- PDLIM1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.884); catalogued as COSV61474627; called by muse, mutect2, varscan2
- PDPR | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99848643; called by muse, mutect2
- PGK1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100965358; called by muse, mutect2, varscan2
- PIWIL1 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.386); catalogued as COSV55346511, COSV99806728; called by muse, mutect2
- PKD2L1 | c.1195G>T p.V399L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV58397884; called by muse, mutect2, varscan2
- PPL | c.3130G>T p.E1044* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs1166367325, COSV52170989; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2289+1G>T p.X763_splice | Splice Site (SNP) | VAF 34/121 reads (28%) | catalogued as rs1243764579, COSV51486173; called by muse, mutect2, varscan2
- RANBP2 | c.4775G>T p.S1592I | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV51705781; called by muse, mutect2, varscan2
- RECK | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as COSV65036007; called by muse, mutect2, varscan2
- SP140 | c.2284-17_2284del p.X762_splice | Splice Site (DEL) | VAF 16/95 reads (17%) | catalogued as COSV59453254; called by mutect2, varscan2
- STK36 | c.2988G>T p.M996I | Missense Mutation (SNP) | VAF 5/117 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99831745; called by muse, mutect2
- TAL2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV61883981; called by muse, mutect2, varscan2
- TG | c.1870G>A p.G624R | Missense Mutation (SNP) | VAF 55/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55088620; called by muse, mutect2, varscan2
- TRANK1 | c.5402A>T p.Y1801F | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57159561; called by muse, mutect2, varscan2
- WASHC3 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV53532904; called by muse, mutect2, varscan2
- WDR61 | c.829-1G>A p.X277_splice | Splice Site (SNP) | VAF 31/96 reads (32%) | catalogued as COSV51217377; called by muse, mutect2, varscan2
- ZFAND5 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52988549; called by muse, mutect2
- ZFHX3 | c.8369A>T p.K2790I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51729144; called by muse, mutect2, varscan2
- ZNF486 | c.971G>A p.C324Y | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100631381, COSV58718855; called by muse, mutect2
- ZNF790 | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs199662090; called by muse, mutect2, varscan2
- COP1 | c.1736_1744del p.C579_H581del | In Frame Del (DEL) | VAF 26/92 reads (28%) | called by mutect2, pindel, varscan2
- MS4A14 | c.1385_1392del p.S462Yfs*10 | Frame Shift Del (DEL) | VAF 41/181 reads (23%) | called by mutect2, pindel, varscan2
- NF1 | c.4431-22_4437del p.X1477_splice (on ENST00000358273 / NM_001042492.3; = p.X1456_splice on NM_000267.3) | Splice Site (DEL) | VAF 17/131 reads (13%) | called by mutect2, pindel
- SF3B4 | c.124_125dup p.H43Pfs*21 | Frame Shift Ins (INS) | VAF 33/106 reads (31%) | called by mutect2, pindel, varscan2
- TLN2 | c.3018_3036del p.K1007* | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- TP53 | c.486dup p.Y163Lfs*18 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- ZHX1 | c.1285_1318del p.S429Qfs*21 | Frame Shift Del (DEL) | VAF 66/212 reads (31%) | called by mutect2, pindel
- ALMS1 | c.5004G>A p.R1668= | Silent (SNP) | VAF 27/288 reads (9%) | catalogued as rs1432669722, COSV100043250; called by muse, mutect2
- APOB | c.726C>T p.S242= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV51945894; called by mutect2, varscan2
- DACH2 | c.636G>A p.P212= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs868343257, COSV64187251; called by muse, mutect2
- DCDC1 | c.2109G>A p.L703= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV60852876; called by muse, mutect2, varscan2
- GCNT3 | c.141T>C p.S47= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV68532376; called by muse, mutect2, varscan2
- KLRB1 | c.336C>G p.V112= | Silent (SNP) | VAF 27/572 reads (5%) | catalogued as COSV99987301; called by muse, mutect2
- LRRC58 | c.861T>G p.L287= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs754246322, COSV55230859; called by muse, mutect2, varscan2
- LUZP1 | c.1416A>C p.S472= | Silent (SNP) | VAF 103/414 reads (25%) | catalogued as COSV56503876; called by muse, mutect2, varscan2
- NCOA3 | c.2154C>T p.D718= | Silent (SNP) | VAF 67/185 reads (36%) | catalogued as rs371484815; called by muse, mutect2, varscan2
- OR4S2 | c.135G>T p.L45= | Silent (SNP) | VAF 114/408 reads (28%) | catalogued as COSV56747407; called by muse, mutect2, varscan2
- CCL4L2 | c.*136A>G | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- LINC00518 | n.1064G>A | RNA (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
